Somatic mutation profile of tumor specimen TCGA-DD-A3A1-01A (aliquot TCGA-DD-A3A1-01A-11D-A20W-10) from TCGA case TCGA-DD-A3A1, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 65.8 years (24,046 days).
Specimen TCGA-DD-A3A1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fdc1cd7f-8b85-4949-9cee-3067e66a8eb3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A1-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A1-11A-11D-A20W-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9e7437f-6e1f-4419-a0da-6de7280ccf3f

The open-access MAF lists 185 somatic variants for this specimen: 161 protein-altering or splice-affecting, 18 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Frame Shift Del 110, Missense Mutation 39, Silent 18, Splice Site 8, Nonsense Mutation 3, Intron 2, 3'UTR 2, RNA 1, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 38/113 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- ACACB | c.6273del p.I2092Ffs*5 | Frame Shift Del (DEL) | VAF 8/91 reads (9%) | catalogued as rs751366693; called by mutect2, pindel
- ACADVL | c.170C>A p.S57Y | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV50037880; called by mutect2, varscan2
- AKAP3 | c.1495del p.D499Ifs*29 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | catalogued as COSV57414634; called by mutect2, pindel
- ANKK1 | c.1552del p.A518Lfs*10 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as rs1272691654; called by mutect2, pindel
- APBA1 | c.609del p.D203Efs*71 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | catalogued as COSV55230602; called by mutect2, pindel
- APLP2 | c.2171T>G p.I724S | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53842440; called by muse, mutect2, varscan2
- CASD1 | c.826G>C p.E276Q | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.784); catalogued as COSV51974085; called by mutect2, varscan2
- CELF6 | c.1042G>T p.G348C | Missense Mutation (SNP) | VAF 66/172 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.687); catalogued as COSV54716576, COSV54717716; called by mutect2, varscan2
- CHRM5 | c.820T>C p.S274P | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as COSV67248010; called by muse, mutect2, varscan2
- CLUH | c.976del p.Q326Rfs*80 (on ENST00000435359; = p.Q364Rfs*80 on NM_015229.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/86 reads (9%) | catalogued as rs1418382371; called by pindel, varscan2
- CNTROB | c.2121G>C p.E707D | Missense Mutation (SNP) | VAF 62/113 reads (55%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); catalogued as COSV66608760; called by mutect2, varscan2
- CPA5 | c.914C>T p.A305V | Missense Mutation (SNP) | VAF 76/255 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1554408794, COSV62570236; called by mutect2, varscan2
- CSMD3 | c.3946C>A p.R1316S (on ENST00000297405 / NM_001363185.1; = p.R1212S on NM_052900.3) | Missense Mutation (SNP) | VAF 30/115 reads (26%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.557); catalogued as COSV52170361, COSV52249274, COSV52271911; called by mutect2, varscan2
- CXCL9 | c.312del p.K104Nfs*8 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | catalogued as COSV53578362; called by pindel, varscan2
- DNAAF2 | c.1398del p.S467Pfs*68 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | catalogued as COSV100024083; called by mutect2, pindel
- EDN3 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 58/160 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1329097336, COSV61108966; ClinVar: uncertain significance; called by mutect2, varscan2
- FAM13A | c.2915T>G p.F972C | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52007988; called by muse, mutect2, varscan2
- FAM8A1 | c.433C>T p.Q145* | Nonsense Mutation (SNP) | VAF 24/69 reads (35%) | catalogued as COSV52582316; called by mutect2, varscan2
- FKRP | c.1078del p.D360Tfs*68 | Frame Shift Del (DEL) | VAF 5/51 reads (10%) | catalogued as CM148890; called by mutect2, pindel
- FLRT2 | c.1199del p.P400Lfs*18 | Frame Shift Del (DEL) | VAF 6/52 reads (12%) | catalogued as COSV58138028; called by mutect2, pindel
- GIPR | c.819del p.W274Gfs*2 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | catalogued as COSV54425955; called by mutect2, pindel
- GPR17 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as rs151092449; called by mutect2, varscan2
- HP1BP3 | c.119del p.P40Rfs*6 | Frame Shift Del (DEL) | VAF 4/22 reads (18%) | catalogued as COSV56561324; called by mutect2, pindel
- IL18 | c.137C>G p.S46* | Nonsense Mutation (SNP) | VAF 31/88 reads (35%) | catalogued as COSV54782232; called by mutect2, varscan2
- KANK1 | c.2308T>C p.Y770H | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); catalogued as COSV63213892; called by mutect2, varscan2
- KIAA0100 | c.2689A>G p.M897V | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV66494981; called by mutect2, varscan2
- KLF4 | c.1059del p.D354Ifs*90 | Frame Shift Del (DEL) | VAF 6/56 reads (11%) | catalogued as COSV101012748; called by mutect2, pindel
- KRTAP26-1 | c.436C>A p.Q146K | Missense Mutation (SNP) | VAF 56/118 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as COSV62129076; called by mutect2, varscan2
- LARP1B | c.828C>A p.S276R | Missense Mutation (SNP) | VAF 40/98 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52800290; called by mutect2, varscan2
- LMTK3 | c.3573del p.S1192Afs*124 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | catalogued as COSV54309508; called by mutect2, pindel
- MCAT | c.383C>T p.S128L | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777075641, COSV51793105; called by mutect2, varscan2
- MED10 | c.309+1G>A p.X103_splice | Splice Site (SNP) | VAF 46/226 reads (20%) | catalogued as COSV55386395; called by mutect2, varscan2
- NEGR1 | c.227G>A p.S76N | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.52); PolyPhen benign (0.124); catalogued as rs760633817, COSV60858700; called by mutect2, varscan2
- OPTC | c.732+1del | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | catalogued as COSV65868371; called by mutect2, pindel
- OR5F1 | c.737C>T p.T246I | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.41); catalogued as rs377087548, COSV53547607; called by mutect2, varscan2
- PAQR7 | c.914A>C p.E305A | Missense Mutation (SNP) | VAF 114/209 reads (55%) | SIFT tolerated (0.59); PolyPhen benign (0.097); catalogued as COSV65352011; called by mutect2, varscan2
- PATJ | c.2189G>T p.G730V | Missense Mutation (SNP) | VAF 52/299 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.061); catalogued as COSV57167042; called by mutect2, varscan2
- PDE9A | c.209del p.N70Ifs*9 | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | catalogued as COSV52326496; called by mutect2, pindel
- PLEKHG1 | c.1466A>G p.Q489R | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV62049270; called by muse, mutect2, varscan2
- PLPP7 | c.473C>T p.T158M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs781554300, COSV64841333; called by muse, varscan2
- POLE | c.4853A>G p.N1618S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs775952114, COSV57685670; called by mutect2, varscan2
- PPP2R5B | c.1178A>G p.N393S | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.742); catalogued as COSV51211297; called by mutect2, varscan2
- PRKRA | c.678del p.N227Tfs*3 | Frame Shift Del (DEL) | VAF 20/112 reads (18%) | catalogued as COSV100359405; called by mutect2, varscan2
- PRRC2B | c.3940del p.R1314Gfs*152 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | catalogued as COSV61941469; called by mutect2, pindel
- RAB32 | c.543A>G p.I181M | Missense Mutation (SNP) | VAF 34/56 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1312341806, COSV62249345; called by mutect2, varscan2
- REXO1 | c.2954del p.S985* | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | catalogued as COSV99402710; called by mutect2, pindel
- RGS7 | c.784-2A>G p.X262_splice | Splice Site (SNP) | VAF 21/75 reads (28%) | catalogued as COSV58551342; called by muse, mutect2, varscan2
- SEMA3G | c.913del p.H305Tfs*5 | Frame Shift Del (DEL) | VAF 7/82 reads (9%) | catalogued as COSV99202518; called by mutect2, pindel
- SKAP1 | c.163del p.D55Ifs*45 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV100412013; called by mutect2, pindel
- SLC8A1 | c.2430G>T p.M810I | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.57); PolyPhen benign (0.026); catalogued as COSV60489298; called by mutect2, varscan2
- SLITRK3 | c.327del p.N110Tfs*18 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | catalogued as COSV53851376; called by mutect2, pindel
- SYT9 | c.425C>T p.T142M | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.26); PolyPhen benign (0.011); catalogued as rs200034628; called by muse, varscan2
- TBX22 | c.650T>C p.M217T | Missense Mutation (SNP) | VAF 40/58 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV64787056; called by muse, varscan2
- TENT5D | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.02); catalogued as COSV57636489; called by muse, mutect2, varscan2
- THAP1 | c.350G>T p.G117V | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.636); catalogued as COSV54273492; called by mutect2, varscan2
- THAP2 | c.678del p.F227Sfs*10 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | catalogued as COSV57349218; called by mutect2, pindel
- TIGD7 | c.1201A>G p.N401D | Missense Mutation (SNP) | VAF 62/190 reads (33%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.968); catalogued as COSV51916435; called by mutect2, varscan2
- TTC17 | c.386G>C p.G129A | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.985); catalogued as COSV50013223; called by mutect2, varscan2
- UNC13C | c.4016C>A p.S1339Y | Missense Mutation (SNP) | VAF 81/256 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV52900256; called by mutect2, varscan2
- XIRP2 | c.5717G>A p.R1906K (on ENST00000628543; = p.R2081K on NM_152381.6) | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV54717858; called by mutect2, varscan2
- ZNF24 | c.104A>G p.E35G | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.018); catalogued as COSV54348984; called by mutect2, varscan2
- ZNF24 | c.103G>T p.E35* | Nonsense Mutation (SNP) | VAF 20/55 reads (36%) | catalogued as COSV54347972, COSV54348993; called by mutect2, varscan2
- ZNF394 | c.1426A>G p.K476E | Missense Mutation (SNP) | VAF 58/192 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV61794205; called by mutect2, varscan2
- ZNF395 | c.920+1G>A p.X307_splice | Splice Site (SNP) | VAF 25/91 reads (27%) | catalogued as COSV60429613; called by mutect2, varscan2
- ZNF441 | c.1584del p.R529Dfs*50 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | catalogued as COSV100777474; called by mutect2, pindel
- ABHD8 | c.287del p.G96Afs*106 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel
- AL645922.1 | c.2658del p.I887Sfs*3 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- AOC2 | c.303del p.K102Rfs*33 | Frame Shift Del (DEL) | VAF 6/67 reads (9%) | called by mutect2, pindel, varscan2
- ARCN1 | c.1081del p.V361Cfs*2 | Frame Shift Del (DEL) | VAF 7/66 reads (11%) | called by mutect2, pindel
- ARHGAP35 | c.4451del p.P1484Qfs*315 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- ASCC3 | c.2051del p.T684Nfs*14 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- B4GALT6 | c.899+1del p.X300_splice | Splice Site (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- C11orf80 | c.350del p.G117Afs*8 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel
- C22orf31 | c.449del p.K150Rfs*5 | Frame Shift Del (DEL) | VAF 6/50 reads (12%) | called by mutect2, pindel
- C3orf33 | c.577del p.I193Sfs*14 (on ENST00000340171 / NM_001308229.2; = p.I150Sfs*14 on NM_173657.2) | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- CACNA1G | c.5802del p.I1935Yfs*4 | Frame Shift Del (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
- CAPN6 | c.1761del p.K587Nfs*22 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- CAPRIN2 | c.1992del p.E666Nfs*45 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- CCDC9 | c.1475del p.P492Hfs*17 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- CDKN3 | c.193+2del p.X65_splice | Splice Site (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- CENPH | c.672del p.V225Sfs*22 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- CNGB1 | c.3613del p.R1207Gfs*17 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- COL9A3 | c.773del p.P258Qfs*275 | Frame Shift Del (DEL) | VAF 6/78 reads (8%) | called by mutect2, pindel
- CTDP1 | c.1157del p.G386Afs*254 | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- DLGAP3 | c.2349del p.D784Tfs*103 | Frame Shift Del (DEL) | VAF 5/55 reads (9%) | called by mutect2, pindel
- DMRT1 | c.977del p.P326Rfs*61 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- EFCAB13 | c.923del p.K308Sfs*5 | Frame Shift Del (DEL) | VAF 6/70 reads (9%) | called by mutect2, pindel
- EPX | c.1744del p.Q582Sfs*12 | Frame Shift Del (DEL) | VAF 6/72 reads (8%) | called by mutect2, pindel
- FDX2 | c.310del p.L104Wfs*18 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- FLG | c.10987C>G p.Q3663E | Missense Mutation (SNP) | VAF 84/148 reads (57%) | SIFT tolerated (0.18); PolyPhen benign (0.151); called by mutect2, varscan2
- FLYWCH1 | c.883del p.A295Lfs*29 (on ENST00000253928 / NM_001308068.2; = p.A294Lfs*29 on NM_020912.1 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- FMN1 | c.3774del p.S1259Pfs*9 (on ENST00000616417 / NM_001277313.2; = p.S1036Pfs*9 on NM_001103184.4) | Frame Shift Del (DEL) | VAF 4/27 reads (15%) | called by mutect2, pindel
- FNBP4 | c.2044del p.S682Lfs*59 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- GBA3 | c.923del p.Y308Ffs*6 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- GPAM | c.1528_1548delinsAT p.F510Ifs*17 | Frame Shift Del (DEL) | VAF 16/84 reads (19%) | called by pindel, varscan2*
- GPR65 | c.307del p.A103Hfs*18 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- HAS3 | c.766del p.S256Pfs*3 | Frame Shift Del (DEL) | VAF 3/20 reads (15%) | called by mutect2, pindel
- HAUS6 | c.2806+1del p.X936_splice | Splice Site (DEL) | VAF 6/55 reads (11%) | called by mutect2, pindel
- HEXIM1 | c.36del p.Q12Hfs*17 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- HSD17B10 | c.242del p.K81Sfs*7 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- HSPB7 | c.357del p.M119Ifs*19 | Frame Shift Del (DEL) | VAF 3/29 reads (10%) | called by mutect2, pindel
- INF2 | c.1874del p.K625Rfs*15 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- KCNA3 | c.598del p.D200Tfs*129 | Frame Shift Del (DEL) | VAF 41/108 reads (38%) | called by pindel, varscan2
- LIPC | c.1490del p.K497Rfs*6 | Frame Shift Del (DEL) | VAF 3/32 reads (9%) | called by mutect2, pindel
- LRFN4 | c.1663del p.H555Tfs*69 | Frame Shift Del (DEL) | VAF 5/50 reads (10%) | called by mutect2, pindel
- LRRK1 | c.2058del p.R687Efs*75 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- MAEL | c.353del p.L118* | Frame Shift Del (DEL) | VAF 5/35 reads (14%) | called by mutect2, pindel
- MAGEB3 | c.995del p.G332Afs*27 | Frame Shift Del (DEL) | VAF 3/26 reads (12%) | called by mutect2, pindel
- MED1 | c.3227del p.K1076Sfs*39 | Frame Shift Del (DEL) | VAF 10/115 reads (9%) | called by mutect2, pindel
- MED14 | c.1865del p.P622Qfs*2 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MIA3 | c.5722del p.*1908Kfs*21 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- MIEF1 | c.314del p.F105Sfs*20 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- MON1B | c.1255del p.D419Tfs*17 | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- MPPED1 | c.369del p.L124Sfs*5 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- MYH4 | c.4473del p.Y1492Tfs*11 | Frame Shift Del (DEL) | VAF 6/66 reads (9%) | called by mutect2, pindel
- MYH7B | c.5062del p.Q1688Rfs*6 | Frame Shift Del (DEL) | VAF 5/53 reads (9%) | called by mutect2, pindel
- NFX1 | c.2649del p.A884Lfs*3 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- NKX2-2 | c.819del p.W273Cfs*44 | Frame Shift Del (DEL) | VAF 3/21 reads (14%) | called by mutect2, pindel
- NKX2-8 | c.298del p.E100Sfs*40 | Frame Shift Del (DEL) | VAF 4/28 reads (14%) | called by mutect2, pindel
- NR1D2 | c.1337del p.L446* | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- NUMBL | c.607del p.E203Rfs*121 | Frame Shift Del (DEL) | VAF 8/64 reads (13%) | called by mutect2, pindel
- P3H3 | c.2186del p.A729Dfs*21 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PADI1 | c.1299del p.S434Afs*19 | Frame Shift Del (DEL) | VAF 3/30 reads (10%) | called by mutect2, pindel
- PCDHGA1 | c.868del p.Q290Kfs*5 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, pindel
- PCM1 | c.4419del p.F1473Lfs*12 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- PHF20L1 | c.11del p.K4Sfs*70 | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- PHF3 | c.4382del p.N1461Ifs*27 | Frame Shift Del (DEL) | VAF 4/48 reads (8%) | called by mutect2, varscan2
- PHKG2 | c.1168del p.E390Rfs*7 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- PNPLA6 | c.1249del p.R417Afs*99 (on ENST00000414982 / NM_001166111.2; = p.R369Afs*99 on NM_006702.5) | Frame Shift Del (DEL) | VAF 3/33 reads (9%) | called by mutect2, pindel
- PPFIBP2 | c.2430del p.V811Sfs*6 | Frame Shift Del (DEL) | VAF 4/35 reads (11%) | called by mutect2, pindel
- PTPRF | c.1812del p.T605Pfs*9 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- PTPRU | c.4278+2del p.X1426_splice | Splice Site (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- RAPH1 | c.1124del p.E375Gfs*20 (on ENST00000319170 / NM_213589.3; = p.E427Gfs*20 on NM_203365.4) | Frame Shift Del (DEL) | VAF 4/42 reads (10%) | called by mutect2, pindel
- RBM26 | c.1911del p.E638Sfs*27 (on ENST00000438737 / NM_001366735.2; = p.E635Sfs*33 on NM_022118.5) | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by mutect2, pindel
- RGS17 | c.106del p.C36Afs*8 | Frame Shift Del (DEL) | VAF 5/54 reads (9%) | called by mutect2, pindel
- RGS22 | c.2411del p.K804Sfs*88 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, pindel
- RNF122 | c.64del p.S22Pfs*85 | Frame Shift Del (DEL) | VAF 6/65 reads (9%) | called by mutect2, pindel
- SDR42E1 | c.857del p.L286Wfs*8 | Frame Shift Del (DEL) | VAF 5/63 reads (8%) | called by mutect2, pindel
- SHANK1 | c.4646del p.P1549Lfs*76 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- SLC25A5 | c.552del p.I185Sfs*31 | Frame Shift Del (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- SMOC2 | c.967del p.D323Tfs*25 (on ENST00000356284 / NM_001166412.2; = p.D334Tfs*25 on NM_022138.3) | Frame Shift Del (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- SON | c.369del p.E124Kfs*25 | Frame Shift Del (DEL) | VAF 3/27 reads (11%) | called by mutect2, pindel
- SPATA31A3 | c.3237A>T p.R1079S | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.208); called by mutect2, varscan2
- SVIL | c.3431del p.N1144Tfs*39 (on ENST00000355867 / NM_021738.3; = p.N718Tfs*39 on NM_003174.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- TGM5 | c.223del p.A75Lfs*28 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- TJP3 | c.2757del p.*920Dfs*? | Frame Shift Del (DEL) | VAF 6/84 reads (7%) | called by mutect2, pindel
- TMEM230 | c.226del p.A76Qfs*8 | Frame Shift Del (DEL) | VAF 6/58 reads (10%) | called by mutect2, varscan2
- TSTD2 | c.483-2del p.X161_splice | Splice Site (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- UBR4 | c.7557del p.S2520Vfs*29 | Frame Shift Del (DEL) | VAF 3/18 reads (17%) | called by mutect2, pindel
- UBR7 | c.1257del p.M420Cfs*27 | Frame Shift Del (DEL) | VAF 3/31 reads (10%) | called by mutect2, pindel
- UTS2R | c.825del p.W275Cfs*25 | Frame Shift Del (DEL) | VAF 4/40 reads (10%) | called by mutect2, pindel
- ZFHX3 | c.8311del p.S2771Pfs*18 | Frame Shift Del (DEL) | VAF 4/44 reads (9%) | called by mutect2, pindel
- ZFP1 | c.923del p.K308Sfs*36 | Frame Shift Del (DEL) | VAF 3/35 reads (9%) | called by mutect2, pindel
- ZFP36 | c.897_899del p.S300del (on ENST00000594442; = p.S294del on NM_003407.5) | In Frame Del (DEL) | VAF 14/69 reads (20%) | called by pindel, varscan2
- ZNF33B | c.1804del p.T602Hfs*31 | Frame Shift Del (DEL) | VAF 4/46 reads (9%) | called by mutect2, pindel
- ZNF425 | c.1117del p.L373* | Frame Shift Del (DEL) | VAF 3/34 reads (9%) | called by mutect2, pindel
- ZNF507 | c.817del p.E273Rfs*16 | Frame Shift Del (DEL) | VAF 6/62 reads (10%) | called by mutect2, pindel
- ZNF559 | c.1192del p.S398Vfs*9 | Frame Shift Del (DEL) | VAF 10/88 reads (11%) | called by mutect2, pindel
- ZNF569 | c.813del p.C272Vfs*74 | Frame Shift Del (DEL) | VAF 3/24 reads (13%) | called by mutect2, pindel
- ZNF7 | c.1540del p.Y514Tfs*23 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- ADGRA3 | c.1485G>A p.L495= | Silent (SNP) | VAF 65/183 reads (36%) | catalogued as COSV51565930; called by mutect2, varscan2
- AQP3 | c.702A>G p.A234= | Silent (SNP) | VAF 22/58 reads (38%) | catalogued as rs755461857, COSV53048688, COSV53048709; called by muse, varscan2
- CHST3 | c.1053C>T p.S351= | Silent (SNP) | VAF 17/36 reads (47%) | catalogued as rs1341613061, COSV64151379; called by muse, mutect2, varscan2
- COMP | c.502C>T p.L168= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV55875676; called by mutect2, varscan2
- DCP1A | c.987A>T p.A329= | Silent (SNP) | VAF 128/368 reads (35%) | catalogued as COSV53689580; called by mutect2, varscan2
- DOCK9 | c.3534G>A p.R1178= (on ENST00000376460 / NM_001366676.2; = p.R1179= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 37/105 reads (35%) | catalogued as rs975069475, COSV59636662; called by mutect2, varscan2
- EFCAB6 | c.3798C>T p.D1266= | Silent (SNP) | VAF 44/126 reads (35%) | catalogued as rs144783076; called by mutect2, varscan2
- FANCF | c.792T>C p.T264= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as COSV59416706; called by mutect2, varscan2
- HDGFL1 | c.258C>G p.P86= | Silent (SNP) | VAF 5/21 reads (24%) | called by muse, mutect2
- IGF1R | c.2694G>A p.P898= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as rs146023463; called by mutect2, varscan2
- LRP12 | c.2397C>T p.A799= | Silent (SNP) | VAF 31/140 reads (22%) | catalogued as COSV52631655; called by mutect2, varscan2
- MUC5B | c.15732G>A p.K5244= | Silent (SNP) | VAF 48/154 reads (31%) | catalogued as COSV71594207; called by mutect2, varscan2
- MYPOP | c.1119C>T p.L373= | Silent (SNP) | VAF 22/68 reads (32%) | catalogued as COSV56194397; called by muse, mutect2, varscan2
- PCDHA11 | c.366G>A p.E122= | Silent (SNP) | VAF 61/120 reads (51%) | catalogued as rs781981842, COSV56513766; called by mutect2, varscan2
- PRUNE2 | c.4383G>A p.K1461= | Silent (SNP) | VAF 40/143 reads (28%) | catalogued as COSV65044215; called by mutect2, varscan2
- RAC2 | c.558G>A p.K186= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV50774868; called by muse, varscan2
- TMEM132B | c.2478A>G p.R826= | Silent (SNP) | VAF 42/148 reads (28%) | catalogued as COSV54761245; called by mutect2, varscan2
- VAMP2 | c.240C>T p.S80= | Silent (SNP) | VAF 12/120 reads (10%) | catalogued as rs777323970, COSV57183478; called by mutect2, varscan2
- AC073310.1 | n.341del | RNA (DEL) | VAF 3/28 reads (11%) | called by mutect2, pindel
- CAPN1 | chr11:65214066 C>T | 3'Flank (SNP) | VAF 18/54 reads (33%) | catalogued as rs764514687; called by mutect2, varscan2
- DKC1 | c.*1del | 3'UTR (DEL) | VAF 4/45 reads (9%) | called by mutect2, pindel
- GLRX5 | c.*3del | 3'UTR (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel
- KDM5A | c.4867-520del | Intron (DEL) | VAF 3/25 reads (12%) | called by mutect2, pindel
- PCDHA3 | c.2394+60del | Intron (DEL) | VAF 5/56 reads (9%) | called by mutect2, pindel
